Surgical pathology report (de-identified scan), TCGA case TCGA-F6-A8O3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Asterand, specimen TCGA-F6-A8O3-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumors is located in Brain, Frontal Lobe, with 6x5x5cm in size, soft and brown-white surface, moderately-margin.

Microscopic Description: Tumor is increased cellularity and hemogenous. Nuclei are round and irregular and hyperchromatic. Mitotic figures are present. Tumor cells have moderate, eosinophilic or clear cytoplasm around a central spherical nucleus. Tumor tissue intervenes in thin vascular and invades into begin brain tissue. Tumor is necrotic. Vasculae are hyperplastic.

Diagnosis Details: Oligodendroglioma, grade II

Comments:

Formatted Path Reports: Brain tumor checklist

Diagnosis: Oligodendroglioma of the brain

Tumor location: Brain, Frontal Lobe

Tumor grade: Poorly differentiated

Tumor size: 6 x 5 x 5 cm

Diagnosis details: None

Comments: None

ICD-O-3
Oligodendroglioma, grade II
CSCF 9450/3
Site Brain, supratentorial C71.0
path Brain, frontal lobe C71.1
J. J 11/26/13

Source: NCI Genomic Data Commons file e33354e8-64ce-42c9-80a3-964f316c1b7e (TCGA-F6-A8O3.79D96BBD-E399-4928-A86A-FF5086045841.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).